Gene-level copy-number profile of tumor specimen CUPP-B4JE-TTM1-A from CCG case CUPP-B4JE, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.9 years (23,721 days).
Specimen CUPP-B4JE-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a6ab55e-0ef7-4182-aceb-7441b9da021f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4JE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/dac02806-d2c8-4da2-aaf0-26e634c8668a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,624; copy number 2: 53,973; copy number 3: 1,314.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 774. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
